Somatic mutation profile of tumor specimen HCM-BROD-0679-C43-06A (aliquot HCM-BROD-0679-C43-06A-11D-A80U-36) from HCMI case HCM-BROD-0679-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.3 years (24,933 days).
Specimen HCM-BROD-0679-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00cd2dca-4349-487b-89f3-7a290a7c8f47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0679-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0679-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30583b43-653b-430f-ace8-41fda23d3b9d

The open-access MAF lists 856 somatic variants for this specimen: 540 protein-altering or splice-affecting, 279 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 486, Silent 279, Nonsense Mutation 32, Intron 25, Splice Region 10, Splice Site 6, 3'UTR 4, 5'Flank 3, Frame Shift Del 3, RNA 3, 5'UTR 2, In Frame Del 1.

Variants (750 of 856; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.6752G>A p.G2251E | Missense Mutation (SNP) | VAF 247/547 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs121912834, CM071647, CM980412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 173/411 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.2713C>T p.P905S (on ENST00000502732 / NM_007314.4; = p.P890S on NM_005158.5) | Missense Mutation (SNP) | VAF 650/1077 reads (60%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV61011371; called by muse, mutect2, varscan2
- ACR | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 255/666 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.116); catalogued as rs368710046, COSV53360743; called by muse, mutect2, varscan2
- ADAMTSL4 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 294/951 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55009047, COSV99648185; called by muse, mutect2, varscan2
- ADCY5 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs1311371744, COSV100567509; called by muse, mutect2, varscan2
- ADGRV1 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV67981171; called by muse, mutect2, varscan2
- ADH7 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 233/487 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146193104; called by muse, mutect2, varscan2
- AGBL3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs746965087, COSV51950655; called by mutect2, varscan2
- AMELX | c.144G>A p.P48= | Splice Region (SNP) | VAF 38/63 reads (60%) | catalogued as rs149068672, COSV61629208; called by muse, mutect2, varscan2
- ARHGAP17 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 153/355 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs112438139, COSV99253854; called by muse, mutect2, varscan2
- ARHGEF38 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 146/335 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs1367584311; called by muse, mutect2, varscan2
- ARID2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 88/242 reads (36%) | catalogued as COSV57596634; called by muse, mutect2, varscan2
- ARID3B | c.1574C>T p.P525L (on ENST00000622429 / NM_001307939.1; = p.P524L on NM_006465.4) | Missense Mutation (SNP) | VAF 219/622 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs760067611; called by muse, varscan2
- ARSH | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 298/371 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs755749697; called by muse, mutect2, varscan2
- ASXL1 | c.3865C>G p.R1289G | Missense Mutation (SNP) | VAF 248/543 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV60120509; called by muse, mutect2, varscan2
- ATF4 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 232/560 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57480537; called by muse, mutect2, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, mutect2, varscan2
- ATXN1L | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 221/506 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101449083; called by mutect2, varscan2
- BAIAP2L2 | c.1221_1222insGTGACACCC p.P407_M408insVTP | In Frame Ins (INS) | VAF 161/542 reads (30%) | catalogued as rs1262419647; called by pindel, varscan2
- BAP1 | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 334/733 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56239815; called by muse, mutect2, varscan2
- BCL11A | c.2110G>A p.G704S (on ENST00000335712 / NM_001365609.1; = p.G738S on NM_018014.4) | Missense Mutation (SNP) | VAF 324/677 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1260030200; called by muse, mutect2, varscan2
- BCL11B | c.1057C>T p.P353S (on ENST00000357195 / NM_001282237.2; = p.P282S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 344/845 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as rs1211809833; called by muse, mutect2, varscan2
- BRINP3 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 267/446 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66535691; called by muse, mutect2, varscan2
- C10orf62 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 263/334 reads (79%) | catalogued as rs1251830927; called by muse, mutect2, varscan2
- C14orf39 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs760333498, COSV58780487; called by muse, mutect2, varscan2
- CCDC144A | c.1709A>C p.H570P | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as rs1263117301; called by muse, mutect2, varscan2
- CCDC158 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 266/671 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780553927; called by muse, mutect2, varscan2
- CCDC163 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 142/368 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV59151305; called by mutect2, varscan2
- CCRL2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 148/372 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV62193435; called by muse, mutect2, varscan2
- CD300LD | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 113/294 reads (38%) | catalogued as rs868469429, COSV60083582; called by muse, mutect2, varscan2
- CDC20B | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 234/506 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV57051927; called by muse, mutect2, varscan2
- CDHR3 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 218/478 reads (46%) | catalogued as rs756269580; called by muse, mutect2, varscan2
- CELSR3 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 247/597 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1217121769; called by muse, mutect2, varscan2
- CENPC | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs920266566; called by muse, mutect2, varscan2
- CHD5 | c.3110G>A p.R1037Q | Missense Mutation (SNP) | VAF 165/431 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs746052525, COSV52418365, COSV99313761; called by muse, mutect2, varscan2
- CLCA1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 231/526 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs770005577, COSV52326014; called by muse, mutect2, varscan2
- CLDN18 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 175/463 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.165); catalogued as COSV59302390; called by muse, mutect2, varscan2
- CLMN | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs370655092; called by muse, mutect2, varscan2
- CMYA5 | c.7306C>T p.P2436S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV101484368, COSV71404171; called by muse, mutect2, varscan2
- COL14A1 | c.5077G>A p.G1693S | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99918222; called by muse, mutect2, varscan2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by mutect2, varscan2
- COL2A1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 235/555 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs755370440; called by muse, mutect2, varscan2
- COL2A1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 237/558 reads (42%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as COSV100476482; called by muse, mutect2, varscan2
- COL4A2 | c.3035G>A p.G1012E | Missense Mutation (SNP) | VAF 144/413 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64626781; called by muse, mutect2, varscan2
- COL4A3 | c.4243G>A p.G1415R | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM127661; called by muse, mutect2, varscan2
- COL5A2 | c.2672G>A p.G891D | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66408901; called by muse, mutect2, varscan2
- CP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.377); catalogued as rs866999571; called by muse, mutect2, varscan2
- CSDE1 | c.1493G>A p.R498K (on ENST00000358528 / NM_001007553.3; = p.R467K on NM_007158.6) | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs781569478; called by muse, mutect2, varscan2
- CTNND2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 219/535 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV58893142; called by muse, mutect2, varscan2
- CYP1A2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 284/715 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59661466; called by muse, mutect2, varscan2
- CYP2U1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747965749, COSV60549820; ClinVar: uncertain significance; called by mutect2, varscan2
- CYP4A22 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 165/386 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.119); catalogued as rs777084778; called by muse, mutect2, varscan2
- CYP8B1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 212/565 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1157117737; called by muse, mutect2, varscan2
- DAZAP1 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 343/792 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99245503; called by muse, mutect2, varscan2
- DAZAP1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 347/797 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99245465; called by muse, mutect2, varscan2
- DCAF8L1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 267/322 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs777162966, COSV71595354; called by muse, mutect2, varscan2
- DCC | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 255/562 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59134782; called by muse, mutect2, varscan2
- DCN | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV50006533; called by muse, mutect2, varscan2
- DDHD1 | c.1963C>T p.L655F (on ENST00000323669; = p.L852F on NM_030637.3) | Missense Mutation (SNP) | VAF 118/302 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60357397; called by mutect2, varscan2
- DDX28 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 292/687 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs1356807601; called by muse, mutect2, varscan2
- DIS3L | c.1132C>T p.R378* (on ENST00000319212 / NM_001143688.3; = p.R295* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 104/282 reads (37%) | catalogued as rs893215526, COSV59911391; called by mutect2, varscan2
- DNAH12 | c.6163G>A p.E2055K (on ENST00000351747; = p.E2074K on NM_001366028.2) | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.239); catalogued as COSV61059637; called by muse, mutect2, varscan2
- DNAH2 | c.6094C>T p.P2032S | Missense Mutation (SNP) | VAF 192/444 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66720706; called by muse, mutect2, varscan2
- DNAH3 | c.7093G>A p.D2365N | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); catalogued as COSV54503765; called by mutect2, varscan2
- DNAH9 | c.9122C>T p.P3041L | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52362361; called by muse, mutect2, varscan2
- DRD5 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 139/333 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as COSV100431878; called by mutect2, varscan2
- DYSF | c.6101C>T p.T2034I | Missense Mutation (SNP) | VAF 216/580 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs771663815; called by muse, mutect2, varscan2
- EHHADH | c.1844G>A p.S615N | Missense Mutation (SNP) | VAF 164/412 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1176614097; called by muse, mutect2, varscan2
- ENTPD5 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 234/578 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453746383; called by muse, mutect2, varscan2
- EPB41L1 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 167/454 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151643; called by muse, mutect2, varscan2
- EPPIN | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 223/526 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51490972; called by muse, mutect2, varscan2
- EPX | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 158/401 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs755121348, COSV99836352; called by muse, mutect2, varscan2
- ESRRG | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 497/825 reads (60%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as rs1435255843; called by muse, mutect2, varscan2
- FAT4 | c.14104C>T p.R4702* | Nonsense Mutation (SNP) | VAF 231/554 reads (42%) | catalogued as COSV58690372; called by muse, mutect2, varscan2
- FCRL1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 372/634 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV63826946, COSV63827240; called by muse, mutect2, varscan2
- FGF7 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.601); catalogued as rs1195547010, COSV51065826; called by muse, mutect2, varscan2
- FLG | c.8407G>A p.E2803K | Missense Mutation (SNP) | VAF 250/1773 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.082); catalogued as rs370605039; called by muse, mutect2, varscan2
- FLG | c.1928G>A p.R643K | Missense Mutation (SNP) | VAF 574/964 reads (60%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.745); catalogued as rs1291999516, COSV64238885; called by muse, mutect2, varscan2
- FMNL3 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV53301802; called by muse, mutect2, varscan2
- FOLH1 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 150/411 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs767480479; called by muse, mutect2, varscan2
- FOLH1 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs866827421, COSV99923017; called by muse, mutect2, varscan2
- FPR3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV59329223; called by muse, mutect2, varscan2
- FTMT | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 354/867 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100360498, COSV58420205; called by muse, mutect2, varscan2
- GABRE | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 244/313 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs867877489, COSV100944370; called by muse, mutect2, varscan2
- GADL1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); catalogued as rs1261964623; called by muse, mutect2, varscan2
- GLI3 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 296/657 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1241442383, CM107040; called by muse, mutect2, varscan2
- GPR45 | c.527C>G p.P176R | Missense Mutation (SNP) | VAF 337/697 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs374437830; called by muse, mutect2, varscan2
- GRIN2A | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 295/691 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs770546037, COSV58030401; called by muse, mutect2, varscan2
- GXYLT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as rs75740340, COSV99789204; called by muse, mutect2, varscan2
- HEATR5A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 132/347 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324109831; called by muse, mutect2, varscan2
- HLTF | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1420352778; called by muse, mutect2, varscan2
- HPN | c.291G>A p.R97= | Splice Region (SNP) | VAF 208/474 reads (44%) | catalogued as COSV99061007; called by muse, mutect2, varscan2
- HSF2 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 122/270 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780492445; called by muse, mutect2, varscan2
- HTR1A | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 250/581 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1221106719; called by muse, mutect2, varscan2
- HTR3C | c.926-1G>A p.X309_splice | Splice Site (SNP) | VAF 183/437 reads (42%) | catalogued as rs1182784613; called by muse, mutect2, varscan2
- IGLV8-61 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 263/561 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV101135150; called by muse, mutect2, varscan2
- IL12A | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs933440333; called by muse, mutect2, varscan2
- ILDR1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 284/647 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.339); catalogued as COSV56549679; called by muse, mutect2, varscan2
- INTS5 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 359/808 reads (44%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.034); catalogued as rs1042930641; called by muse, mutect2, varscan2
- JAK1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61093408; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 116/289 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 222/513 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562638505; called by muse, mutect2, varscan2
- KCNQ1 | c.1251G>A p.V417= | Splice Region (SNP) | VAF 201/448 reads (45%) | catalogued as rs1369698000; called by muse, mutect2, varscan2
- KCNS1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 398/885 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1407855838; called by muse, mutect2, varscan2
- KCNV1 | c.1495T>A p.W499R | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52085373; called by mutect2, varscan2
- KDM2B | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 262/618 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as rs781826750; called by muse, mutect2, varscan2
- KHDRBS3 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 54/190 reads (28%) | catalogued as rs777562123; called by muse, mutect2, varscan2
- KIAA1109 | c.7645T>G p.Y2549D | Missense Mutation (SNP) | VAF 151/366 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1185081263; called by muse, mutect2, varscan2
- KMT2A | c.7639C>T p.P2547S | Missense Mutation (SNP) | VAF 163/426 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs1555046723; called by muse, mutect2, varscan2
- KMT5B | c.2645G>A p.R882K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1233285083; called by muse, mutect2, varscan2
- KRT24 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 230/540 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs760797312; called by muse, mutect2, varscan2
- KRT84 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 332/702 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1457316224; called by muse, mutect2, varscan2
- L1TD1 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 139/328 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs752701856, COSV63133360; called by muse, mutect2, varscan2
- LAMB4 | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs761572743, COSV52732020; called by muse, mutect2, varscan2
- LENG9 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 286/705 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1349593267; called by muse, mutect2, varscan2
- LRP1B | c.3787A>G p.I1263V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1012095559; called by muse, mutect2, varscan2
- LRRC43 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 314/791 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1412131690; called by muse, mutect2, varscan2
- LRRC45 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 139/353 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1265923233; called by muse, mutect2, varscan2
- MAGEB16 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 356/432 reads (82%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV101303345; called by muse, mutect2, varscan2
- MAP1A | c.4817C>T p.A1606V | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs750022307, COSV55813403; called by muse, mutect2, varscan2
- MAP4K3 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55716906; called by mutect2, varscan2
- MBD3L1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 139/328 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771170768, COSV59775876; called by muse, mutect2, varscan2
- MBD5 | c.3372T>A p.S1124R | Missense Mutation (SNP) | VAF 274/917 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1246420113; called by muse, mutect2, varscan2
- MEI4 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs527596466; called by muse, mutect2, varscan2
- MGAT4C | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1222715246, COSV59830124, COSV59831777; called by mutect2, varscan2
- MICAL2 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 223/535 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs144708456; called by muse, mutect2, varscan2
- MMP11 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 386/847 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as rs780729049; called by muse, mutect2, varscan2
- MORC1 | c.1237A>G p.N413D | Missense Mutation (SNP) | VAF 99/181 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs373695498; called by muse, mutect2, varscan2
- MROH2A | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 215/522 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs766826150, COSV67682690; called by muse, mutect2, varscan2
- MROH2B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1451889213, COSV101270575, COSV101270679; called by muse, mutect2, varscan2
- MS4A8 | c.645C>A p.S215R | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs756117147; called by muse, mutect2, varscan2
- MTARC1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 199/678 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs771876954; called by muse, mutect2, varscan2
- MUC16 | c.33578C>T p.S11193L | Missense Mutation (SNP) | VAF 170/414 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.909); catalogued as COSV67495392; called by muse, mutect2, varscan2
- MUC16 | c.29907T>G p.S9969R | Missense Mutation (SNP) | VAF 170/428 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV67475229; called by mutect2, varscan2
- MUC16 | c.20288G>A p.G6763E | Missense Mutation (SNP) | VAF 282/615 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.033); catalogued as rs369370967; called by muse, mutect2, varscan2
- MUC16 | c.16105C>T p.P5369S | Missense Mutation (SNP) | VAF 252/587 reads (43%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.062); catalogued as COSV67478194; called by muse, mutect2, varscan2
- MUC16 | c.13150G>A p.G4384R | Missense Mutation (SNP) | VAF 183/459 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV101200644; called by muse, mutect2, varscan2
- MYCBPAP | c.468G>A p.Q156= | Splice Region (SNP) | VAF 122/343 reads (36%) | catalogued as COSV60412055; called by muse, mutect2, varscan2
- MYH11 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs376622843; called by muse, mutect2, varscan2
- MYH13 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as rs572952027; called by muse, mutect2, varscan2
- MYH4 | c.2588C>T p.T863I | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs766143426, COSV55127608; called by muse, mutect2, varscan2
- MYH4 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV55111317; called by muse, mutect2, varscan2
- MYOM1 | c.3190C>T p.H1064Y | Missense Mutation (SNP) | VAF 192/487 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755409090; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NBEA | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59762759; called by muse, mutect2, varscan2
- NBEAL2 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 255/601 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.127); catalogued as rs1190003464; called by muse, mutect2, varscan2
- NBL1 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 249/535 reads (47%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.991); catalogued as rs1410289295; called by muse, varscan2
- NCKAP1L | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53203336; called by muse, mutect2, varscan2
- NCKAP5L | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 283/645 reads (44%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.885); catalogued as rs1266010564; called by muse, mutect2, varscan2
- NEU4 | c.175G>A p.G59S (on ENST00000391969 / NM_001167602.3; = p.G71S on NM_080741.4) | Missense Mutation (SNP) | VAF 271/725 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1028727458; called by muse, mutect2, varscan2
- NFKBIE | c.1447C>T p.L483F (on ENST00000275015; = p.L344F on NM_004556.3) | Missense Mutation (SNP) | VAF 125/262 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs1561912982; called by muse, mutect2, varscan2
- NLRP13 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 206/482 reads (43%) | catalogued as COSV100738207; called by muse, mutect2, varscan2
- NLRP2 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 216/521 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs375615677; called by muse, mutect2, varscan2
- NLRP3 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 270/956 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV60229257; called by muse, mutect2, varscan2
- NMUR2 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 265/633 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1352413085, COSV54923197; called by muse, mutect2, varscan2
- NOBOX | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 196/501 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV99779568; called by muse, mutect2, varscan2
- NODAL | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 237/525 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1316642787; called by muse, mutect2, varscan2
- NPHS2 | c.537C>T p.I179= | Splice Region (SNP) | VAF 68/207 reads (33%) | catalogued as rs370260554; called by muse, mutect2, varscan2
- NTRK1 | c.360-1G>A p.X120_splice | Splice Site (SNP) | VAF 142/522 reads (27%) | catalogued as COSV100693566; called by mutect2, varscan2
- OLFM4 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV54578391; called by muse, mutect2, varscan2
- OR10J3 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 389/633 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1251768496; called by muse, mutect2, varscan2
- OR10P1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 259/601 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs374603359, COSV59006615; called by muse, mutect2, varscan2
- OR2A2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 189/515 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV68871596, COSV68871682; called by muse, mutect2, varscan2
- OR4A15 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 182/494 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1428184028, COSV59035680; called by muse, mutect2, varscan2
- OR4A15 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1565113120, COSV59035504; called by muse, mutect2, varscan2
- OR4Q2 | c.525+1G>A | Missense Mutation (SNP) | VAF 159/408 reads (39%) | catalogued as rs895174410; called by muse, mutect2, varscan2
- OR52B6 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 247/577 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61447187; called by muse, mutect2, varscan2
- OR5H14 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs752967855, COSV71194648, COSV71194693; called by muse, mutect2, varscan2
- OR6K6 | c.599A>G p.N200S (on ENST00000368144; = p.N176S on NM_001005184.1) | Missense Mutation (SNP) | VAF 285/928 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1332237429, COSV63744139; called by muse, mutect2, varscan2
- OR7G1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 163/393 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53319147; called by muse, mutect2, varscan2
- OR7G3 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 257/603 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs200054594; called by muse, mutect2, varscan2
- OR8U1 | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV56413879; called by muse, varscan2
- OTOL1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 214/541 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as rs1429646440; called by muse, mutect2, varscan2
- OTOP1 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 246/538 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs140788465; called by muse, mutect2, varscan2
- OTUD7A | c.892G>A p.G298S (on ENST00000307050 / NM_001382637.1; = p.G291S on NM_130901.3) | Missense Mutation (SNP) | VAF 216/574 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1167780057, COSV61037837; called by muse, mutect2, varscan2
- PCDH15 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57281943; called by muse, mutect2, varscan2
- PCDHB4 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 143/379 reads (38%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.179); catalogued as COSV52020239, COSV99522329; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 165/348 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGB5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 156/416 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366423528; called by muse, mutect2, varscan2
- PCNX4 | c.1148C>T p.S383F (on ENST00000406854 / NM_001330177.2; = p.S149F on NM_022495.5) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as rs1305310519, COSV58302415; called by muse, mutect2, varscan2
- PCSK1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 175/437 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); catalogued as COSV60737491; called by muse, mutect2, varscan2
- PDE3A | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV62968633; called by muse, varscan2
- PDHA2 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 192/414 reads (46%) | catalogued as COSV54778995; called by muse, mutect2, varscan2
- PER2 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 310/733 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1008195179; called by muse, mutect2, varscan2
- PES1 | c.799T>A p.L267M | Missense Mutation (SNP) | VAF 253/628 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV58828614; called by muse, mutect2, varscan2
- PIGR | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 240/784 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs748382437; called by muse, mutect2, varscan2
- PIWIL3 | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1569093103; called by mutect2, varscan2
- PLCH1 | c.3425G>A p.R1142K (on ENST00000340059 / NM_001130960.2; = p.R1134K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV58205006; called by muse, mutect2, varscan2
- PLCXD2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 241/545 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.736); catalogued as rs377101481, COSV67342400; called by muse, mutect2, varscan2
- PLEKHG5 | c.706C>T p.P236S (on ENST00000400915 / NM_001042663.3; = p.P199S on NM_020631.6) | Missense Mutation (SNP) | VAF 150/354 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); catalogued as rs1157862488; called by muse, mutect2, varscan2
- PLXNA4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 226/576 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs267601293, COSV58119180; called by muse, mutect2, varscan2
- POU6F2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 280/681 reads (41%) | catalogued as COSV68883041; called by muse, mutect2, varscan2
- PPP1R21 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.633); catalogued as rs1396493130; called by muse, mutect2, varscan2
- PPP1R37 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 345/829 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.945); catalogued as rs757743404; called by muse, mutect2, varscan2
- PRAG1 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 288/690 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as COSV58161076; called by muse, mutect2, varscan2
- PRB4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 348/762 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374921001, COSV54395119; called by muse, mutect2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 227/533 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- PRRG3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 494/612 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs950659306, COSV64851468; called by muse, mutect2, varscan2
- PTCD1 | c.1553C>G p.A518G | Missense Mutation (SNP) | VAF 265/653 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV99464673; called by muse, mutect2, varscan2
- PTPRU | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 231/527 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749851774; called by muse, mutect2, varscan2
- RAD54L2 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 324/714 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1234750870, COSV99621493; called by muse, mutect2, varscan2
- RANBP3L | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 26/91 reads (29%) | catalogued as COSV56955487; called by muse, mutect2, varscan2
- RCSD1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 249/940 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.154); catalogued as COSV63257769; called by muse, mutect2, varscan2
- RFX6 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60584285; called by muse, mutect2, varscan2
- RFX6 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 230/503 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1326581635, COSV60587925; called by muse, mutect2, varscan2
- RGSL1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 161/555 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.448); catalogued as rs1327737019, COSV99679401; called by muse, mutect2, varscan2
- RHO | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 221/565 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs200095648; called by muse, mutect2, varscan2
- RHOH | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 237/555 reads (43%) | catalogued as rs1416692929, COSV67805097; called by muse, mutect2, varscan2
- RHOT1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1251712158; called by muse, mutect2, varscan2
- RIPOR2 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 185/433 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418115; called by muse, mutect2, varscan2
- RUVBL2 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 194/429 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780165337; called by muse, mutect2, varscan2
- RYR3 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 247/533 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747820461, COSV66786499; called by muse, mutect2, varscan2
- SACS | c.7907C>T p.P2636L | Missense Mutation (SNP) | VAF 134/175 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101207251; called by muse, mutect2, varscan2
- SAMHD1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 135/327 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1234364779; called by muse, mutect2, varscan2
- SDK2 | c.4423C>T p.R1475* | Nonsense Mutation (SNP) | VAF 150/417 reads (36%) | catalogued as rs866006487; called by muse, mutect2, varscan2
- SDK2 | c.4422C>G p.F1474L | Missense Mutation (SNP) | VAF 150/413 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.181); catalogued as rs1487436688; called by muse, mutect2, varscan2
- SEMG1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV54871876, COSV54872313; called by mutect2, varscan2
- SFI1 | c.2093G>A p.R698Q (on ENST00000400288 / NM_001007467.3; = p.R667Q on NM_014775.4) | Missense Mutation (SNP) | VAF 240/492 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs753089246, COSV101191831; called by muse, mutect2, varscan2
- SH3BP2 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 482/1047 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs867169595; called by muse, mutect2, varscan2
- SHBG | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 206/516 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.165); catalogued as rs183272852; called by muse, mutect2, varscan2
- SHC2 | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 289/689 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs532732139, COSV52747911; called by muse, mutect2, varscan2
- SIPA1L3 | c.4349C>T p.P1450L | Missense Mutation (SNP) | VAF 279/666 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs548838198, COSV99727390; called by muse, mutect2, varscan2
- SIRT7 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 158/401 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs567589929, COSV100155711, COSV58711732; called by mutect2, varscan2
- SLC10A2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 235/537 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55361364; called by muse, mutect2, varscan2
- SLC16A12 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 162/215 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100369994, COSV57950826; called by muse, mutect2, varscan2
- SLC17A7 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 206/550 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs990263659, COSV55546290, COSV55547088; called by muse, mutect2, varscan2
- SLC28A1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 191/425 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs768377268, COSV54476945; called by muse, mutect2, varscan2
- SLC39A2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 257/638 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs138590006; called by muse, mutect2, varscan2
- SPEG | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 287/705 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs759841206; called by muse, mutect2, varscan2
- SPHKAP | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 234/539 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1487343994; called by muse, mutect2, varscan2
- SPOCD1 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 284/708 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.188); catalogued as rs757160383, COSV57096392; called by muse, mutect2, varscan2
- ST8SIA3 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 104/241 reads (43%) | catalogued as COSV60653415; called by muse, mutect2, varscan2
- STYX | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV63463579; called by muse, mutect2, varscan2
- SV2A | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 227/705 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100975127; called by muse, mutect2, varscan2
- SYNGAP1 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 437/982 reads (45%) | catalogued as rs1554121947; called by muse, mutect2, varscan2
- SYT1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54039227, COSV99693692; called by muse, mutect2, varscan2
- SYTL2 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV60363612; called by muse, mutect2, varscan2
- TAF1C | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 312/793 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs757737958, COSV100499593; called by muse, mutect2, varscan2
- TBC1D4 | c.3575C>T p.S1192F | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs762526748; called by muse, mutect2, varscan2
- TFDP2 | c.362G>A p.R121Q (on ENST00000489671 / NM_001178139.2; = p.R60Q on NM_006286.5) | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs1298190375; called by muse, mutect2, varscan2
- THSD4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1285714444, COSV99964731; called by muse, mutect2, varscan2
- TIMM44 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778758579, COSV54490251; called by mutect2, varscan2
- TLR3 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as COSV57167730; called by muse, varscan2
- TLR5 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60561272; called by muse, mutect2, varscan2
- TMEM131L | c.3404G>A p.R1135K | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs773923664; called by muse, mutect2, varscan2
- TMEM132D | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 192/502 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs764597587, COSV101243030; called by muse, varscan2
- TMPRSS7 | c.908C>T p.S303F (on ENST00000452346; = p.S177F on NM_001042575.2) | Missense Mutation (SNP) | VAF 175/473 reads (37%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.961); catalogued as COSV101340073; called by muse, mutect2, varscan2
- TNFRSF1A | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 291/735 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.442); catalogued as rs1473547216; called by muse, mutect2, varscan2
- TPH2 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 78/215 reads (36%) | catalogued as COSV61590776; called by muse, mutect2, varscan2
- TRBC2 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 276/612 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.62); catalogued as rs1554512573; called by muse, mutect2, varscan2
- TRIM17 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 168/551 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1398441920; called by muse, mutect2, varscan2
- TRIM61 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.37); catalogued as rs1238874561; called by muse, mutect2, varscan2
- TRIOBP | c.3910C>T p.R1304C | Missense Mutation (SNP) | VAF 319/723 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs550274094; called by muse, mutect2, varscan2
- TRPA1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 194/511 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51566183; called by muse, mutect2, varscan2
- UGT2A3 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 94/245 reads (38%) | catalogued as COSV52360874; called by muse, mutect2, varscan2
- UNC13C | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 165/431 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as rs1451262581, COSV52912943; called by muse, mutect2, varscan2
- VPS13C | c.3685G>T p.V1229L (on ENST00000644861 / NM_020821.3; = p.V1186L on NM_017684.5) | Missense Mutation (SNP) | VAF 182/394 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs766371434; called by muse, mutect2, varscan2
- VPS13D | c.3373T>G p.F1125V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50623202; called by muse, mutect2, varscan2
- WDR47 | c.2693C>T p.T898I (on ENST00000369962 / NM_001142551.2; = p.T899I on NM_014969.5) | Missense Mutation (SNP) | VAF 250/587 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV63059366; called by muse, mutect2, varscan2
- WDR86 | c.727-8C>T | Splice Region (SNP) | VAF 293/726 reads (40%) | catalogued as rs968732791, COSV100561217; called by muse, mutect2, varscan2
- WIF1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV54131993; called by muse, mutect2
- YME1L1 | c.935C>T p.P312L (on ENST00000326799 / NM_139312.3; = p.P255L on NM_014263.4) | Missense Mutation (SNP) | VAF 81/112 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100463436; called by muse, mutect2, varscan2
- ZBTB49 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 144/376 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs1265588413; called by mutect2, varscan2
- ZC3H13 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 195/417 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs754240291, COSV54450719; called by muse, mutect2, varscan2
- ZFHX4 | c.4571G>A p.R1524K | Missense Mutation (SNP) | VAF 166/359 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV50597469; called by muse, mutect2, varscan2
- ZIC1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 393/943 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51557666; called by muse, mutect2, varscan2
- ZNF253 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63037253; called by muse, mutect2, varscan2
- ZNF304 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 225/521 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99988760; called by muse, mutect2, varscan2
- ZNF420 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.882); catalogued as rs775994644, COSV58492526; called by mutect2, varscan2
- ZNF462 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 173/216 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs745724742, COSV52936186; called by muse, mutect2, varscan2
- ZNF469 | c.9715C>T p.P3239S (on ENST00000437464; = p.P3267S on NM_001367624.2) | Missense Mutation (SNP) | VAF 340/835 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs528159004; called by muse, mutect2, varscan2
- ZNF469 | c.9716C>T p.P3239L (on ENST00000437464; = p.P3267L on NM_001367624.2) | Missense Mutation (SNP) | VAF 343/834 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1205639918; called by muse, mutect2, varscan2
- ZNF479 | c.1454G>A p.R485K | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58637819, COSV58643680; called by muse, varscan2
- ZNF681 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV101267409; called by muse, mutect2
- ZNF681 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV101267392; called by muse, mutect2, varscan2
- AADAC | c.846T>A p.N282K | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC9 | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ACAD10 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 149/349 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTR1B | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 249/579 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAD1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2837G>A p.W946* | Nonsense Mutation (SNP) | VAF 175/421 reads (42%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.2838G>A p.W946* | Nonsense Mutation (SNP) | VAF 175/422 reads (41%) | called by muse, mutect2, varscan2
- ADGRF2 | c.752C>T p.S251F (on ENST00000296862 / NM_001368115.2; = p.S183F on NM_153839.7) | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADPRH | c.492C>A p.H164Q | Missense Mutation (SNP) | VAF 313/687 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADPRHL1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 231/518 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- AFAP1 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 248/605 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- AFF1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 312/690 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 144/344 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by mutect2, varscan2
- AJUBA | c.1322T>G p.F441C | Missense Mutation (SNP) | VAF 216/533 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ALCAM | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- AQP4 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ARAP2 | c.979A>T p.N327Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by mutect2, varscan2
- ARHGEF10L | c.1795G>C p.V599L | Missense Mutation (SNP) | VAF 234/585 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ARHGEF15 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 271/687 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF15 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 275/700 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 402/977 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- BCAS3 | c.2422C>T p.P808S (on ENST00000390652 / NM_001353144.2; = p.P793S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/586 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- BICRAL | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 216/518 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- BNIPL | c.662G>A p.C221Y | Missense Mutation (SNP) | VAF 144/466 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRSK1 | c.612G>A p.G204= | Splice Region (SNP) | VAF 274/604 reads (45%) | called by muse, mutect2, varscan2
- BRSK1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 268/574 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRSK2 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 267/612 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- C3orf20 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 175/363 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CAMSAP2 | c.767G>T p.C256F (on ENST00000236925 / NM_001297707.2; = p.C245F on NM_203459.3) | Missense Mutation (SNP) | VAF 216/416 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBLL2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 326/401 reads (81%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC93 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 181/455 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNB3 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 134/170 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CD55 | c.586T>A p.L196I | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- CD5L | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 488/801 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH10 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 172/386 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, varscan2
- CDH11 | c.1748G>T p.S583I | Missense Mutation (SNP) | VAF 328/746 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CDH13 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 209/491 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH23 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 286/632 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEMIP | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 231/557 reads (41%) | called by muse, mutect2, varscan2
- CENPC | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP290 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by mutect2, varscan2
- CFAP54 | c.3077T>C p.V1026A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by mutect2, varscan2
- CGN | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 227/748 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CHAT | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 218/480 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST3 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 285/672 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CKAP4 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 274/655 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CKM | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 150/366 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- CLCN3 | c.807A>T p.L269F | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CNKSR3 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 151/371 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CNOT6L | c.361C>T p.L121F (on ENST00000504123 / NM_001286790.2; = p.L116F on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- COL15A1 | c.3319C>T p.P1107S | Missense Mutation (SNP) | VAF 198/247 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- COL1A1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 253/573 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- COL5A2 | c.3571G>A p.G1191R | Missense Mutation (SNP) | VAF 188/473 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 206/497 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE3 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CRB1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 238/782 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CSMD2 | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 259/585 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNKA2IP | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUX1 | c.4392_4408del p.A1465Lfs*80 | Frame Shift Del (DEL) | VAF 210/588 reads (36%) | called by pindel, varscan2
- CUZD1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 93/125 reads (74%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CWF19L1 | c.1201A>T p.K401* | Nonsense Mutation (SNP) | VAF 162/202 reads (80%) | called by muse, mutect2, varscan2
- CXorf21 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 176/217 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CYP11A1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 219/565 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- DCAF10 | c.827A>T p.N276I | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX30 | c.-123G>A | Splice Region (SNP) | VAF 172/449 reads (38%) | called by muse, mutect2, varscan2
- DMRTC1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DSP | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- E2F8 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELOA3D | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 221/1169 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ESPNL | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 266/665 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EVC | c.1685A>T p.Q562L | Missense Mutation (SNP) | VAF 237/561 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FAM205A | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by mutect2, varscan2
- FAM214B | c.1577C>T p.T526I | Missense Mutation (SNP) | VAF 249/319 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- FAR1 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- FER1L5 | c.1655-1G>A p.X552_splice (on ENST00000623019; = p.X557_splice on NM_001293083.2) | Splice Site (SNP) | VAF 134/328 reads (41%) | called by muse, mutect2, varscan2
- FES | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 248/520 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FEZ1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 138/350 reads (39%) | called by muse, mutect2, varscan2
- FGD2 | c.685-1G>A p.X229_splice | Splice Site (SNP) | VAF 147/319 reads (46%) | called by muse, mutect2, varscan2
- FOXK2 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 131/347 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSTL5 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- FXYD6 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 155/400 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- FYN | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 229/572 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABRB1 | c.836-1G>A p.X279_splice | Splice Site (SNP) | VAF 94/230 reads (41%) | called by muse, mutect2, varscan2
- GALR3 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 468/981 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCKR | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 191/515 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GIMAP6 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 298/688 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GOLGA3 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 247/518 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGB1 | c.8856C>T p.L2952= | Splice Region (SNP) | VAF 93/233 reads (40%) | called by muse, mutect2, varscan2
- GP1BA | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 228/527 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GPD2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 158/408 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPR149 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 159/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR182 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 330/750 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRIN2D | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 329/838 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- GRM1 | c.2287C>T p.L763F | Missense Mutation (SNP) | VAF 209/548 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HBA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 158/817 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS3ST6 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 325/953 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- HSD17B8 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 263/597 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR1E | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 180/465 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HYDIN | c.9263C>T p.S3088F | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- IBTK | c.2872A>G p.I958V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- IFNA13 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.044); called by mutect2, varscan2
- IFNE | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 86/115 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV6D-41 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IGSF9B | c.3772C>T p.P1258S | Missense Mutation (SNP) | VAF 347/883 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- INAVA | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 214/660 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- INPPL1 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 169/521 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IRS2 | c.925T>G p.S309A | Missense Mutation (SNP) | VAF 391/863 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KCNRG | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 131/289 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCTD9 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KDM5B | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 234/778 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- KIAA1671 | c.3584G>A p.R1195K | Missense Mutation (SNP) | VAF 156/359 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); called by mutect2, varscan2
- KRBA1 | c.2662C>A p.L888M | Missense Mutation (SNP) | VAF 297/746 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP5-10 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 154/436 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.661); called by mutect2, varscan2
- LCE6A | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 402/671 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- LCK | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 264/576 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- LRRC43 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 298/723 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC69 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MANBA | c.2147C>T p.S716F (on ENST00000642252; = p.S670F on NM_005908.4) | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MAP1A | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 238/553 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARF1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 236/519 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MBOAT4 | c.1087T>C p.S363P | Missense Mutation (SNP) | VAF 184/392 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MED23 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 161/359 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- MEX3D | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 368/842 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MGAM | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MLXIPL | c.1929C>A p.D643E | Missense Mutation (SNP) | VAF 175/442 reads (40%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MMP27 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 179/428 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MOV10L1 | c.2967G>C p.R989S | Missense Mutation (SNP) | VAF 264/614 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MPP7 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC16 | c.43352C>T p.P14451L | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 226/556 reads (41%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- MUC22 | c.4388C>T p.S1463F | Missense Mutation (SNP) | VAF 339/812 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- MYH15 | c.5378G>A p.R1793K | Missense Mutation (SNP) | VAF 158/414 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MYO10 | c.6002C>T p.S2001F | Missense Mutation (SNP) | VAF 281/614 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO10 | c.4760C>T p.P1587L | Missense Mutation (SNP) | VAF 245/628 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYRFL | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NBEA | c.5341C>T p.P1781S | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NCAM1 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 174/410 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NCKIPSD | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 246/559 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NDUFB4 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEMF | c.109T>A p.Y37N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NF1 | c.7205C>T p.S2402L (on ENST00000358273 / NM_001042492.3; = p.S2381L on NM_000267.3) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NLRP5 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 305/683 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NOBOX | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 231/554 reads (42%) | called by muse, mutect2
- NPAT | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRP2 | c.2786C>T p.S929F (on ENST00000360409 / NM_201266.2; = p.S924F on NM_003872.3) | Missense Mutation (SNP) | VAF 151/316 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NUP153 | c.2272C>T p.L758F | Missense Mutation (SNP) | VAF 159/400 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NWD1 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 238/593 reads (40%) | called by muse, mutect2, varscan2
- NXPE2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OCIAD2 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by mutect2, varscan2
- OCM | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ONECUT3 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 314/688 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ONECUT3 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 312/684 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPN5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52L1 | c.821T>A p.I274N | Missense Mutation (SNP) | VAF 193/429 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- OSBPL7 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 312/799 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOF | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 230/559 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OXLD1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 274/642 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PABPC4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 165/391 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PAK6 | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 259/615 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALB2 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PCCA | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 289/709 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCDH12 | c.1656G>A p.W552* | Nonsense Mutation (SNP) | VAF 250/609 reads (41%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1440G>A p.W480* | Nonsense Mutation (SNP) | VAF 413/917 reads (45%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCM1 | c.2788A>T p.N930Y | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- PDE11A | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PEX16 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 176/454 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by mutect2, varscan2
- PEX5 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIGC | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 194/595 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PIK3R6 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITHD1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 355/833 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PLA2G4D | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 324/746 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PLA2G4E | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 250/543 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEK2 | c.352A>T p.R118* | Nonsense Mutation (SNP) | VAF 275/602 reads (46%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PLIN3 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 204/447 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- POSTN | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PRAMEF14 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 200/458 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRAMEF17 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 136/277 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PROP1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 320/750 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PRSS41 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 228/546 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PTPN14 | c.3210G>T p.W1070C | Missense Mutation (SNP) | VAF 60/818 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRM | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 242/575 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGAPA1 | c.5251_5265del p.D1751_P1755del | In Frame Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- RARS1 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL1 | c.1182G>A p.R394= | Splice Region (SNP) | VAF 190/395 reads (48%) | called by muse, mutect2, varscan2
- RCC1L | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 153/360 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RGSL1 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 130/525 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, varscan2
- RNF128 | c.635C>T p.S212F (on ENST00000255499 / NM_194463.2; = p.S186F on NM_024539.3) | Missense Mutation (SNP) | VAF 104/133 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RPS6KA2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 196/476 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTN4RL1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 334/728 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUFY4 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 263/599 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- SALL1 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 288/342 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SCGB1D4 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- SCRIB | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 358/825 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.121); called by muse, varscan2
- SDR9C7 | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SELP | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 214/669 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEMA3F | c.1801T>C p.F601L | Missense Mutation (SNP) | VAF 224/612 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SEMA4G | c.2278G>A p.E760K (on ENST00000370250; = p.E765K on NM_017893.3) | Missense Mutation (SNP) | VAF 209/274 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SERPINB12 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 193/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIDT2 | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 180/433 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by mutect2, varscan2
- SLC16A14 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 173/438 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC17A7 | c.1410C>G p.Y470* | Nonsense Mutation (SNP) | VAF 160/385 reads (42%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1956C>A p.S652R (on ENST00000517878 / NM_001286646.2; = p.S601R on NM_001080431.2) | Missense Mutation (SNP) | VAF 135/310 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLITRK4 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1B | c.2630G>C p.R877P | Missense Mutation (SNP) | VAF 175/441 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SNX6 | c.347G>A p.R116K (on ENST00000652385; = p.R104K on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPAG6 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SRGAP1 | c.2306C>T p.S769F | Missense Mutation (SNP) | VAF 232/541 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ST7 | c.1003C>T p.H335Y (on ENST00000265437 / NM_021908.3; = p.H312Y on NM_018412.4) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE4 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 361/845 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SYT10 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 141/343 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAAR9 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TAMALIN | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 81/750 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TAS2R38 | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 150/392 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBL3 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 266/682 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET3 | c.4991T>G p.L1664R | Missense Mutation (SNP) | VAF 337/773 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.2315A>G p.D772G (on ENST00000256246; = p.D1155G on NM_001350162.2) | Missense Mutation (SNP) | VAF 114/263 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFR2 | c.1139G>A p.W380* | Nonsense Mutation (SNP) | VAF 192/453 reads (42%) | called by muse, mutect2, varscan2
- TGFBR3 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 231/511 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TM9SF4 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 163/362 reads (45%) | called by muse, mutect2, varscan2
- TMEM242 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 212/512 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM270 | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 141/328 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TMEM63C | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMPRSS11B | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TNFRSF11A | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 148/312 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOP3A | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 252/630 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAJ49 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 120/322 reads (37%) | PolyPhen probably damaging (1); called by mutect2, varscan2
- TTBK2 | c.3604A>T p.R1202W | Missense Mutation (SNP) | VAF 266/644 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TTC23L | c.905_921del p.L302Cfs*13 | Frame Shift Del (DEL) | VAF 81/271 reads (30%) | called by mutect2, pindel, varscan2
- TTC30B | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 274/642 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTN | c.80840A>C p.E26947A (on ENST00000591111; = p.E19523A on NM_003319.4) | Missense Mutation (SNP) | VAF 123/277 reads (44%) | PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.66994A>C p.K22332Q (on ENST00000591111; = p.K14908Q on NM_003319.4) | Missense Mutation (SNP) | VAF 186/436 reads (43%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBB8B | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 135/366 reads (37%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 276/648 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TXNDC9 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBXN2A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 183/432 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP11 | c.2396C>T p.P799L (on ENST00000218348; = p.P756L on NM_001371072.1) | Missense Mutation (SNP) | VAF 184/252 reads (73%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP24 | c.4450C>T p.L1484F | Missense Mutation (SNP) | VAF 221/496 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- VAT1L | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.3571G>A p.E1191K (on ENST00000628543; = p.E1366K on NM_152381.6) | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- XIRP2 | c.6293C>T p.P2098L (on ENST00000628543; = p.P2273L on NM_152381.6) | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- YME1L1 | c.934C>T p.P312S (on ENST00000326799 / NM_139312.3; = p.P255S on NM_014263.4) | Missense Mutation (SNP) | VAF 82/113 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB49 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by mutect2, varscan2
- ZBTB7C | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 320/735 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H3 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 397/869 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFHX2 | c.4664_4665del p.P1555Rfs*3 | Frame Shift Del (DEL) | VAF 213/618 reads (34%) | called by mutect2, pindel, varscan2
- ZFP57 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 306/702 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZIC1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 395/946 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF100 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); called by mutect2, varscan2
- ZNF180 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF267 | c.1054T>G p.W352G | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF366 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 236/595 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ZNF408 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 326/726 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF445 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 163/383 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF486 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ZNF488 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 256/658 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2
- ZNF573 | c.1831G>A p.E611K (on ENST00000536220 / NM_001172692.1; = p.E553K on NM_152360.3) | Missense Mutation (SNP) | VAF 93/236 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF607 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 102/288 reads (35%) | called by muse, mutect2, varscan2
- ZNF737 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ZNF80 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 207/651 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF813 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF835 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 302/631 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZPBP2 | c.384G>C p.K128N (on ENST00000348931 / NM_199321.3; = p.K106N on NM_198844.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSWIM6 | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 224/490 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABAT | c.18C>T p.L6= | Silent (SNP) | VAF 214/464 reads (46%) | catalogued as rs766349160; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCC11 | c.1497G>A p.R499= | Silent (SNP) | VAF 372/468 reads (79%) | catalogued as rs777449253, COSV62323019; called by muse, mutect2, varscan2
- ABCC9 | c.4626C>T p.S1542= | Silent (SNP) | VAF 102/305 reads (33%) | catalogued as rs771917219; called by muse, mutect2, varscan2
- ABCG2 | c.549C>T p.I183= | Silent (SNP) | VAF 91/177 reads (51%) | called by muse, mutect2, varscan2
- ACRBP | c.1404G>A p.Q468= | Silent (SNP) | VAF 162/410 reads (40%) | called by muse, mutect2, varscan2
- ADAM23 | c.2190C>T p.A730= | Silent (SNP) | VAF 232/570 reads (41%) | called by muse, mutect2, varscan2
- ADAM29 | c.1251G>A p.K417= | Silent (SNP) | VAF 192/452 reads (42%) | catalogued as rs145402389; called by muse, mutect2, varscan2
- ADAM7 | c.1206C>T p.F402= | Silent (SNP) | VAF 107/242 reads (44%) | called by muse, mutect2, varscan2
- ADGRB2 | c.3613C>T p.L1205= | Silent (SNP) | VAF 126/380 reads (33%) | catalogued as COSV57070460; called by muse, mutect2, varscan2
- ADGRB2 | c.3612C>T p.F1204= | Silent (SNP) | VAF 129/386 reads (33%) | catalogued as rs551659755; called by muse, mutect2, varscan2
- ADSL | c.1365G>A p.Q455= | Silent (SNP) | VAF 112/290 reads (39%) | catalogued as rs1011687452; called by muse, mutect2, varscan2
- AK9 | c.1122A>G p.P374= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs529670344; called by mutect2, varscan2
- ANKRD24 | c.2835G>A p.K945= | Silent (SNP) | VAF 399/1014 reads (39%) | called by muse, mutect2, varscan2
- APLNR | c.936C>T p.F312= | Silent (SNP) | VAF 209/491 reads (43%) | catalogued as rs753058631, COSV57241797; called by muse, mutect2, varscan2
- APMAP | c.1209C>T p.F403= | Silent (SNP) | VAF 203/489 reads (42%) | catalogued as COSV54173685; called by muse, mutect2, varscan2
- ARG1 | c.51G>A p.K17= | Silent (SNP) | VAF 182/409 reads (44%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.1794G>A p.V598= | Silent (SNP) | VAF 235/585 reads (40%) | called by muse, mutect2, varscan2
- ARHGEF15 | c.2280G>A p.Q760= | Silent (SNP) | VAF 217/514 reads (42%) | called by muse, mutect2, varscan2
- ASIC4 | c.1272C>T p.L424= (on ENST00000347842 / NM_182847.3; = p.L443= on NM_018674.6) | Silent (SNP) | VAF 197/513 reads (38%) | catalogued as rs752194666; called by muse, mutect2, varscan2
- ASXL1 | c.3864T>G p.G1288= | Silent (SNP) | VAF 245/540 reads (45%) | catalogued as COSV60106323; called by muse, mutect2, varscan2
- ATF4 | c.732G>A p.R244= | Silent (SNP) | VAF 209/516 reads (41%) | called by muse, varscan2
- BRSK2 | c.744G>A p.R248= | Silent (SNP) | VAF 269/615 reads (44%) | called by muse, mutect2, varscan2
- C12orf71 | c.672C>T p.I224= | Silent (SNP) | VAF 249/594 reads (42%) | catalogued as COSV70282920; called by muse, mutect2, varscan2
- CA6 | c.723G>A p.R241= | Silent (SNP) | VAF 159/344 reads (46%) | called by muse, mutect2, varscan2
- CACNA1A | c.1692C>T p.F564= | Silent (SNP) | VAF 128/330 reads (39%) | catalogued as rs377320715; called by mutect2, varscan2
- CACNA1D | c.3939C>T p.I1313= (on ENST00000350061 / NM_001128840.3; = p.I1333= on NM_000720.4) | Silent (SNP) | VAF 132/345 reads (38%) | called by muse, mutect2
- CACNA2D1 | c.2904C>T p.S968= (on ENST00000356253 / NM_001366867.1; = p.S956= on NM_000722.4) | Silent (SNP) | VAF 136/371 reads (37%) | catalogued as COSV62374844; called by muse, mutect2, varscan2
- CAPZA3 | c.387G>A p.V129= | Silent (SNP) | VAF 74/210 reads (35%) | called by muse, mutect2, varscan2
- CARS1 | c.1242C>T p.F414= | Silent (SNP) | VAF 191/403 reads (47%) | called by muse, mutect2, varscan2
- CATSPER4 | c.1068C>T p.L356= | Silent (SNP) | VAF 304/725 reads (42%) | called by muse, mutect2, varscan2
- CCDC163 | c.414C>T p.S138= | Silent (SNP) | VAF 140/363 reads (39%) | catalogued as COSV100517015; called by mutect2, varscan2
- CCDC181 | c.1059G>A p.L353= | Silent (SNP) | VAF 89/140 reads (64%) | catalogued as rs1295448521, COSV63158283; called by muse, mutect2, varscan2
- CCDC182 | c.306G>A p.R102= | Silent (SNP) | VAF 277/651 reads (43%) | catalogued as rs1314587914; called by muse, mutect2, varscan2
- CCNB3 | c.3522C>T p.S1174= | Silent (SNP) | VAF 133/169 reads (79%) | catalogued as COSV52073028; called by muse, mutect2, varscan2
- CCT8L2 | c.414G>A p.T138= | Silent (SNP) | VAF 189/600 reads (32%) | catalogued as rs760129001, COSV63461676, COSV63462106; called by muse, mutect2, varscan2
- CD101 | c.36C>T p.L12= | Silent (SNP) | VAF 155/398 reads (39%) | called by muse, mutect2, varscan2
- CD8A | c.201C>T p.P67= | Silent (SNP) | VAF 309/742 reads (42%) | called by muse, mutect2, varscan2
- CDH10 | c.897G>A p.G299= | Silent (SNP) | VAF 268/616 reads (44%) | catalogued as rs1185825881, COSV52587367; called by muse, mutect2, varscan2
- CDH10 | c.60C>T p.C20= | Silent (SNP) | VAF 144/340 reads (42%) | catalogued as COSV52570087; called by muse, varscan2
- CDH23 | c.2031C>T p.F677= | Silent (SNP) | VAF 197/464 reads (42%) | catalogued as rs759239589, COSV54925526; called by mutect2, varscan2
- CDH23 | c.7632G>A p.L2544= | Silent (SNP) | VAF 159/360 reads (44%) | catalogued as rs775191895, COSV56456099; called by muse, mutect2, varscan2
- CDKL1 | c.408G>A p.T136= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as COSV53582993; called by muse, mutect2, varscan2
- CDSN | c.919C>T p.L307= | Silent (SNP) | VAF 426/1016 reads (42%) | called by muse, mutect2
- CELSR1 | c.1341C>T p.I447= | Silent (SNP) | VAF 300/670 reads (45%) | catalogued as rs756932458, COSV99418115; called by muse, mutect2, varscan2
- CFAP58 | c.987C>T p.I329= | Silent (SNP) | VAF 140/184 reads (76%) | catalogued as COSV100458795; called by muse, mutect2, varscan2
- CHD5 | c.3111G>A p.R1037= | Silent (SNP) | VAF 163/424 reads (38%) | catalogued as COSV52409047; called by muse, mutect2, varscan2
- CHL1 | c.852G>A p.G284= (on ENST00000397491 / NM_001253387.1; = p.G300= on NM_006614.4) | Silent (SNP) | VAF 108/271 reads (40%) | called by muse, mutect2, varscan2
- CHST3 | c.984G>A p.E328= | Silent (SNP) | VAF 285/676 reads (42%) | called by muse, mutect2, varscan2
- CLCA4 | c.480C>T p.L160= | Silent (SNP) | VAF 133/335 reads (40%) | catalogued as COSV55367612; called by muse, mutect2, varscan2
- CLTC | c.1989C>T p.S663= | Silent (SNP) | VAF 115/279 reads (41%) | called by muse, mutect2, varscan2
- CNOT4 | c.603G>A p.K201= | Silent (SNP) | VAF 92/234 reads (39%) | catalogued as COSV59650705; called by muse, mutect2, varscan2
- COL19A1 | c.1704C>T p.G568= | Silent (SNP) | VAF 197/461 reads (43%) | called by muse, mutect2, varscan2
- COL6A3 | c.2958C>T p.I986= | Silent (SNP) | VAF 211/493 reads (43%) | catalogued as rs145203676; called by muse, mutect2, varscan2
- COL6A5 | c.4536G>A p.G1512= | Silent (SNP) | VAF 198/473 reads (42%) | called by muse, mutect2, varscan2
- CRB2 | c.2289C>T p.F763= | Silent (SNP) | VAF 339/431 reads (79%) | catalogued as COSV63505616; called by muse, mutect2, varscan2
- CREB3L3 | c.1053G>A p.G351= | Silent (SNP) | VAF 239/578 reads (41%) | called by muse, mutect2, varscan2
- CTAGE4 | c.2226C>T p.F742= | Silent (SNP) | VAF 69/732 reads (9%) | catalogued as COSV100967778; called by muse, mutect2, varscan2
- CTNND2 | c.225C>T p.I75= | Silent (SNP) | VAF 267/629 reads (42%) | catalogued as COSV58869893; called by muse, mutect2, varscan2
- CUEDC2 | c.863G>A p.*288= | Silent (SNP) | VAF 158/213 reads (74%) | called by muse, mutect2, varscan2
- CXCR1 | c.660C>T p.F220= | Silent (SNP) | VAF 194/499 reads (39%) | called by muse, mutect2, varscan2
- DACH1 | c.975A>T p.A325= | Silent (SNP) | VAF 129/324 reads (40%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.1080G>A p.E360= | Silent (SNP) | VAF 198/429 reads (46%) | catalogued as COSV100295928, COSV60788575; called by muse, mutect2, varscan2
- DGKZ | c.1851G>A p.E617= (on ENST00000454345 / NM_001105540.2; = p.E429= on NM_003646.4) | Silent (SNP) | VAF 213/514 reads (41%) | called by muse, mutect2, varscan2
- DLL1 | c.1929C>T p.L643= | Silent (SNP) | VAF 312/747 reads (42%) | catalogued as rs758149257, COSV100815974, COSV64536598; called by muse, mutect2, varscan2
- DNAH10 | c.6339C>T p.F2113= (on ENST00000409039; = p.F2052= on NM_207437.3) | Silent (SNP) | VAF 314/826 reads (38%) | catalogued as COSV68996529, COSV69004066; called by muse, mutect2, varscan2
- DNAH10 | c.6534G>A p.G2178= (on ENST00000409039; = p.G2117= on NM_207437.3) | Silent (SNP) | VAF 282/770 reads (37%) | catalogued as rs1290578911, COSV101292051; called by muse, mutect2, varscan2
- DNAJC14 | c.45C>T p.H15= | Silent (SNP) | VAF 180/443 reads (41%) | called by muse, mutect2, varscan2
- DOCK3 | c.2880C>T p.F960= | Silent (SNP) | VAF 235/531 reads (44%) | called by muse, mutect2, varscan2
- DYSF | c.6102C>T p.T2034= | Silent (SNP) | VAF 217/583 reads (37%) | called by muse, mutect2, varscan2
- E4F1 | c.1416C>T p.F472= | Silent (SNP) | VAF 334/829 reads (40%) | catalogued as COSV57039466; called by muse, mutect2, varscan2
- EEF1A2 | c.447C>T p.I149= | Silent (SNP) | VAF 352/788 reads (45%) | catalogued as rs772964838, COSV53208572; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHD2 | c.423C>T p.L141= | Silent (SNP) | VAF 141/329 reads (43%) | catalogued as rs1470367232; called by muse, mutect2, varscan2
- EML4 | c.2274G>A p.R758= | Silent (SNP) | VAF 48/152 reads (32%) | called by muse, mutect2, varscan2
- ENC1 | c.165G>A p.R55= | Silent (SNP) | VAF 203/492 reads (41%) | called by muse, mutect2, varscan2
- EVI5L | c.2022C>T p.G674= | Silent (SNP) | VAF 258/673 reads (38%) | called by muse, mutect2, varscan2
- F2 | c.597C>T p.S199= | Silent (SNP) | VAF 167/451 reads (37%) | catalogued as rs576714300, COSV100319624; called by muse, mutect2, varscan2
- FBXL13 | c.609G>A p.V203= | Silent (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- FBXL7 | c.1024C>T p.L342= | Silent (SNP) | VAF 329/792 reads (42%) | catalogued as rs752807427; called by muse, mutect2, varscan2
- FLG | c.7683G>A p.R2561= | Silent (SNP) | VAF 255/859 reads (30%) | catalogued as rs143745201, COSV64245905, COSV64250535; called by muse, mutect2, varscan2
- FLYWCH2 | c.246G>A p.Q82= | Silent (SNP) | VAF 384/923 reads (42%) | called by muse, mutect2, varscan2
- FMN2 | c.2634C>T p.P878= | Silent (SNP) | VAF 310/1094 reads (28%) | catalogued as rs1369118118, COSV100146950; called by muse, mutect2, varscan2
- FOXD2 | c.1317C>T p.F439= | Silent (SNP) | VAF 392/897 reads (44%) | called by muse, mutect2, varscan2
- FOXK2 | c.1755C>T p.V585= | Silent (SNP) | VAF 131/346 reads (38%) | called by muse, mutect2, varscan2
- FPR3 | c.618C>T p.F206= | Silent (SNP) | VAF 229/512 reads (45%) | catalogued as rs755324777, COSV59328545; called by muse, mutect2, varscan2
- FRMPD4 | c.249G>A p.R83= | Silent (SNP) | VAF 275/365 reads (75%) | catalogued as rs761069076, COSV66222017; called by muse, mutect2, varscan2
- FSTL5 | c.1473C>T p.P491= | Silent (SNP) | VAF 87/249 reads (35%) | catalogued as rs1247464471; called by muse, mutect2, varscan2
- FUT3 | c.696G>A p.G232= | Silent (SNP) | VAF 307/779 reads (39%) | catalogued as rs765224654; called by muse, mutect2, varscan2
- GALNT8 | c.888G>A p.Q296= | Silent (SNP) | VAF 151/378 reads (40%) | called by muse, mutect2, varscan2
- GATA3 | c.567C>T p.P189= | Silent (SNP) | VAF 419/518 reads (81%) | catalogued as rs768165292; called by muse, mutect2, varscan2
- GGA1 | c.876C>T p.N292= | Silent (SNP) | VAF 183/447 reads (41%) | called by muse, mutect2, varscan2
- GGA1 | c.877C>T p.L293= | Silent (SNP) | VAF 183/447 reads (41%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1731G>A p.Q577= | Silent (SNP) | VAF 254/312 reads (81%) | called by muse, mutect2, varscan2
- GRM8 | c.2184G>A p.Q728= | Silent (SNP) | VAF 181/416 reads (44%) | called by muse, mutect2, varscan2
- HDAC9 | c.1656G>A p.V552= | Silent (SNP) | VAF 210/513 reads (41%) | catalogued as COSV101286768; called by muse, mutect2, varscan2
- HIPK1 | c.3231C>T p.L1077= (on ENST00000369558 / NM_001369806.1; = p.L683= on NM_181358.2) | Silent (SNP) | VAF 323/792 reads (41%) | catalogued as rs760001128, COSV61248897; called by muse, mutect2, varscan2
- HIRA | c.2859C>T p.Y953= | Silent (SNP) | VAF 84/205 reads (41%) | catalogued as rs1556010857, COSV54272570; called by muse, mutect2, varscan2
- HOXC13 | c.510G>A p.K170= | Silent (SNP) | VAF 358/782 reads (46%) | catalogued as rs760431752; called by muse, mutect2, varscan2
- HOXD3 | c.762G>A p.K254= | Silent (SNP) | VAF 248/632 reads (39%) | called by muse, mutect2, varscan2
- HPS4 | c.1167C>T p.F389= | Silent (SNP) | VAF 210/478 reads (44%) | called by muse, mutect2, varscan2
- HPS6 | c.2070C>T p.L690= | Silent (SNP) | VAF 336/407 reads (83%) | catalogued as rs1210018155; called by muse, mutect2, varscan2
- HYDIN | c.14079C>T p.P4693= | Silent (SNP) | VAF 129/525 reads (25%) | called by muse, mutect2, varscan2
- IGHM | c.1305G>A p.G435= | Silent (SNP) | VAF 196/406 reads (48%) | catalogued as rs1178554497; called by muse, mutect2, varscan2
- IGLV8-61 | c.249G>A p.G83= | Silent (SNP) | VAF 269/564 reads (48%) | catalogued as rs1412480210; called by muse, mutect2, varscan2
- IKZF2 | c.270G>A p.V90= | Silent (SNP) | VAF 324/766 reads (42%) | catalogued as rs1480206985; called by muse, mutect2, varscan2
- ILDR1 | c.1572G>A p.R524= (on ENST00000344209 / NM_001199799.2; = p.R480= on NM_175924.4) | Silent (SNP) | VAF 136/316 reads (43%) | catalogued as rs1375830170, COSV56549871; called by muse, mutect2, varscan2
- INPPL1 | c.1587T>C p.S529= | Silent (SNP) | VAF 169/520 reads (33%) | called by muse, mutect2, varscan2
- INTS1 | c.4968C>T p.F1656= | Silent (SNP) | VAF 210/463 reads (45%) | catalogued as COSV67177423; called by muse, mutect2, varscan2
- JAG2 | c.3552C>T p.G1184= | Silent (SNP) | VAF 311/777 reads (40%) | called by muse, mutect2, varscan2
- JPH1 | c.1422C>T p.H474= | Silent (SNP) | VAF 237/562 reads (42%) | catalogued as rs777783295; called by muse, mutect2, varscan2
- KCNA6 | c.1302G>A p.G434= | Silent (SNP) | VAF 292/658 reads (44%) | called by muse, mutect2, varscan2
- KIAA1549 | c.4758C>T p.F1586= | Silent (SNP) | VAF 183/418 reads (44%) | called by muse, mutect2, varscan2
- KIF19 | c.918C>T p.L306= | Silent (SNP) | VAF 165/356 reads (46%) | called by muse, mutect2, varscan2
- KITLG | c.768G>A p.E256= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs573914379, COSV57204009; called by muse, mutect2, varscan2
- KLHL14 | c.1413G>A p.G471= | Silent (SNP) | VAF 182/401 reads (45%) | catalogued as COSV63831936; called by muse, mutect2, varscan2
- KLHL14 | c.792C>T p.L264= | Silent (SNP) | VAF 383/853 reads (45%) | catalogued as rs758386114; called by muse, mutect2, varscan2
- KLHL40 | c.1629C>T p.F543= | Silent (SNP) | VAF 194/419 reads (46%) | catalogued as COSV55134672; called by mutect2, varscan2
- KRTAP10-12 | c.135C>T p.A45= | Silent (SNP) | VAF 462/1056 reads (44%) | catalogued as rs1555950771; called by muse, mutect2, varscan2
- LAMB1 | c.2349C>T p.S783= | Silent (SNP) | VAF 249/524 reads (48%) | catalogued as rs775144042, COSV55962240, COSV55969152; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIPK | c.720C>T p.F240= | Silent (SNP) | VAF 146/200 reads (73%) | catalogued as COSV101344960; called by muse, mutect2, varscan2
- LRP1B | c.4806C>T p.V1602= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as COSV101254960, COSV67194478; called by muse, mutect2, varscan2
- LRRC43 | c.21C>T p.S7= | Silent (SNP) | VAF 302/740 reads (41%) | catalogued as rs767979161; called by muse, mutect2, varscan2
- LRRC43 | c.1701G>A p.R567= | Silent (SNP) | VAF 313/791 reads (40%) | catalogued as COSV60291592; called by muse, mutect2, varscan2
- LRRC4C | c.1038G>A p.Q346= | Silent (SNP) | VAF 207/508 reads (41%) | catalogued as COSV53432332, COSV53437506; called by muse, mutect2, varscan2
- MAGEA10 | c.705C>T p.F235= | Silent (SNP) | VAF 257/333 reads (77%) | called by muse, mutect2, varscan2
- MAP1A | c.4818C>T p.A1606= | Silent (SNP) | VAF 118/307 reads (38%) | called by muse, mutect2, varscan2
- MAP3K4 | c.3036C>T p.F1012= | Silent (SNP) | VAF 165/358 reads (46%) | called by muse, mutect2, varscan2
- MARK4 | c.2016C>T p.A672= | Silent (SNP) | VAF 320/751 reads (43%) | called by muse, mutect2, varscan2
- MAS1 | c.402C>T p.V134= | Silent (SNP) | VAF 211/512 reads (41%) | catalogued as rs140242572; called by muse, mutect2, varscan2
- MBD5 | c.4425C>T p.I1475= | Silent (SNP) | VAF 126/319 reads (39%) | catalogued as COSV68695929; called by muse, mutect2, varscan2
- MDN1 | c.4395C>T p.F1465= | Silent (SNP) | VAF 200/483 reads (41%) | catalogued as COSV65518858; called by muse, mutect2, varscan2
- MED26 | c.1689G>A p.V563= | Silent (SNP) | VAF 305/669 reads (46%) | called by muse, mutect2, varscan2
- MEX3D | c.1050C>T p.P350= | Silent (SNP) | VAF 366/834 reads (44%) | catalogued as rs777460785, COSV66312479; called by muse, mutect2, varscan2
- MGAM2 | c.45C>T p.F15= | Silent (SNP) | VAF 122/325 reads (38%) | called by mutect2, varscan2
- MGAM2 | c.2733G>A p.L911= | Silent (SNP) | VAF 249/540 reads (46%) | catalogued as rs1428658015; called by muse, mutect2, varscan2
- MICU1 | c.1152C>T p.Y384= (on ENST00000361114 / NM_001195518.2; = p.Y390= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/182 reads (38%) | catalogued as rs764422809; called by muse, mutect2, varscan2
- MORC1 | c.354G>A p.T118= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs555321094, COSV51713642; called by muse, mutect2, varscan2
- MSS51 | c.288G>A p.Q96= | Silent (SNP) | VAF 208/540 reads (39%) | called by muse, mutect2, varscan2
- MTARC1 | c.324G>A p.Q108= | Silent (SNP) | VAF 194/668 reads (29%) | catalogued as rs147237295; called by muse, mutect2, varscan2
- MTCL1 | c.906C>T p.V302= | Silent (SNP) | VAF 473/1067 reads (44%) | called by muse, mutect2, varscan2
- MUC16 | c.23487G>A p.L7829= | Silent (SNP) | VAF 225/509 reads (44%) | called by muse, mutect2, varscan2
- MUC16 | c.1714C>T p.L572= | Silent (SNP) | VAF 226/528 reads (43%) | catalogued as COSV101199881; called by muse, mutect2, varscan2
- MUC22 | c.3654C>T p.V1218= | Silent (SNP) | VAF 412/973 reads (42%) | called by muse, mutect2, varscan2
- MXRA5 | c.6624G>A p.V2208= | Silent (SNP) | VAF 267/351 reads (76%) | called by muse, mutect2, varscan2
- MYBPH | c.807C>T p.P269= | Silent (SNP) | VAF 199/714 reads (28%) | called by muse, mutect2, varscan2
- MYH1 | c.4263G>A p.T1421= | Silent (SNP) | VAF 160/398 reads (40%) | catalogued as rs370946637; called by mutect2, varscan2
- MYH13 | c.2724G>A p.R908= | Silent (SNP) | VAF 102/315 reads (32%) | catalogued as rs1197533052; called by muse, mutect2, varscan2
- MYH4 | c.2718G>A p.E906= | Silent (SNP) | VAF 70/180 reads (39%) | called by muse, mutect2, varscan2
- MYH4 | c.1527C>T p.I509= | Silent (SNP) | VAF 253/651 reads (39%) | catalogued as rs1462404392, COSV55111358; called by muse, mutect2, varscan2
- MYO1G | c.294C>T p.I98= | Silent (SNP) | VAF 193/404 reads (48%) | catalogued as rs762257344; called by muse, mutect2, varscan2
- MYO5B | c.315C>T p.I105= | Silent (SNP) | VAF 89/217 reads (41%) | catalogued as rs748097712, COSV53215610, COSV53227808; called by muse, mutect2, varscan2
- NAALADL1 | c.321C>T p.S107= | Silent (SNP) | VAF 250/599 reads (42%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2718C>T p.P906= | Silent (SNP) | VAF 260/607 reads (43%) | called by muse, mutect2, varscan2
- NCOA6 | c.5856G>A p.E1952= | Silent (SNP) | VAF 127/296 reads (43%) | catalogued as rs762836072; called by muse, mutect2, varscan2
- NEB | c.19644G>A p.G6548= | Silent (SNP) | VAF 271/684 reads (40%) | called by muse, mutect2
- NEU4 | c.174G>A p.R58= (on ENST00000391969 / NM_001167602.3; = p.R70= on NM_080741.4) | Silent (SNP) | VAF 277/732 reads (38%) | called by muse, mutect2, varscan2
- NLRP5 | c.2686C>T p.L896= | Silent (SNP) | VAF 193/506 reads (38%) | catalogued as rs766306003; called by muse, mutect2, varscan2
- NMT1 | c.687C>T p.I229= | Silent (SNP) | VAF 206/464 reads (44%) | called by muse, mutect2, varscan2
- NOC4L | c.885C>T p.T295= | Silent (SNP) | VAF 198/505 reads (39%) | called by muse, mutect2, varscan2
- NOVA1 | c.795C>T p.S265= | Silent (SNP) | VAF 147/351 reads (42%) | catalogued as COSV57487758; called by muse, mutect2, varscan2
- NPAS3 | c.2436C>T p.T812= (on ENST00000356141 / NM_001164749.2; = p.T780= on NM_022123.3) | Silent (SNP) | VAF 305/741 reads (41%) | called by muse, mutect2, varscan2
- NPAT | c.1281C>T p.A427= | Silent (SNP) | VAF 91/229 reads (40%) | called by muse, mutect2, varscan2
- NRCAM | c.498C>T p.P166= (on ENST00000379028 / NM_001371124.1; = p.P160= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- NRP2 | c.1956G>A p.E652= | Silent (SNP) | VAF 229/560 reads (41%) | called by muse, mutect2, varscan2
- NRXN3 | c.889C>T p.L297= | Silent (SNP) | VAF 293/661 reads (44%) | called by muse, mutect2, varscan2
- NUP153 | c.2271C>T p.A757= | Silent (SNP) | VAF 161/400 reads (40%) | catalogued as COSV50449674; called by muse, mutect2, varscan2
- OR10A7 | c.267G>A p.R89= | Silent (SNP) | VAF 119/310 reads (38%) | catalogued as rs371021969; called by muse, mutect2, varscan2
- OR1M1 | c.81C>T p.L27= | Silent (SNP) | VAF 198/485 reads (41%) | catalogued as COSV101447571; called by muse, mutect2, varscan2
- OR2W3 | c.138C>T p.I46= | Silent (SNP) | VAF 298/1048 reads (28%) | catalogued as COSV64458418; called by muse, mutect2, varscan2
- OR4A8 | c.42C>T p.G14= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs775990977; called by muse, mutect2, varscan2
- OR4A8 | c.180C>T p.F60= | Silent (SNP) | VAF 131/339 reads (39%) | called by muse, mutect2, varscan2
- OR4C12 | c.351C>T p.A117= | Silent (SNP) | VAF 212/474 reads (45%) | called by muse, mutect2, varscan2
- OR51G1 | c.765C>T p.I255= | Silent (SNP) | VAF 176/462 reads (38%) | catalogued as COSV58968324, COSV58969126; called by muse, mutect2, varscan2
- OR5A2 | c.811A>C p.R271= | Silent (SNP) | VAF 182/411 reads (44%) | called by muse, mutect2, varscan2
- OR7A5 | c.135C>T p.I45= | Silent (SNP) | VAF 228/541 reads (42%) | called by muse, mutect2, varscan2
- OSBPL7 | c.2094C>T p.L698= | Silent (SNP) | VAF 314/802 reads (39%) | called by muse, mutect2, varscan2
- PAPPA2 | c.3045G>A p.G1015= | Silent (SNP) | VAF 153/529 reads (29%) | catalogued as COSV62808569; called by muse, mutect2, varscan2
- PCCA | c.48G>A p.R16= | Silent (SNP) | VAF 288/708 reads (41%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2100C>T p.F700= | Silent (SNP) | VAF 426/973 reads (44%) | catalogued as rs782504378; called by muse, mutect2
- PCLO | c.4023G>A p.K1341= | Silent (SNP) | VAF 116/248 reads (47%) | catalogued as COSV61621488, COSV61634106; called by mutect2, varscan2
- PCP2 | c.396G>A p.P132= | Silent (SNP) | VAF 217/525 reads (41%) | catalogued as rs376970140; called by muse, mutect2, varscan2
- PEBP4 | c.420C>T p.S140= | Silent (SNP) | VAF 163/433 reads (38%) | catalogued as rs754251581; called by muse, mutect2, varscan2
- PIEZO1 | c.334C>T p.L112= | Silent (SNP) | VAF 167/375 reads (45%) | called by muse, mutect2, varscan2
- PKD1L3 | c.168A>C p.G56= | Silent (SNP) | VAF 180/436 reads (41%) | called by muse, varscan2
- PLA2G2D | c.69G>A p.L23= | Silent (SNP) | VAF 211/484 reads (44%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.603G>A p.R201= | Silent (SNP) | VAF 160/421 reads (38%) | called by muse, mutect2, varscan2
- PLIN4 | c.1659G>A p.T553= (on ENST00000301286; = p.T568= on NM_001367868.2) | Silent (SNP) | VAF 283/634 reads (45%) | catalogued as rs767265114; called by muse, varscan2
- POLR3G | c.33T>C p.A11= | Silent (SNP) | VAF 53/138 reads (38%) | called by mutect2, varscan2
- POM121L12 | c.420G>A p.G140= | Silent (SNP) | VAF 424/983 reads (43%) | catalogued as COSV68694468; called by muse, mutect2, varscan2
- PPP1R3F | c.1342C>T p.L448= | Silent (SNP) | VAF 463/577 reads (80%) | called by muse, mutect2, varscan2
- PRAM1 | c.492C>T p.A164= | Silent (SNP) | VAF 413/891 reads (46%) | catalogued as COSV99725275; called by muse, mutect2, varscan2
- PREX2 | c.1218C>T p.F406= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV99904486; called by muse, mutect2, varscan2
- PSG7 | c.609C>T p.Y203= | Silent (SNP) | VAF 213/520 reads (41%) | catalogued as rs746719103; called by muse, mutect2, varscan2
- PTAFR | c.786C>T p.F262= | Silent (SNP) | VAF 214/524 reads (41%) | called by muse, mutect2, varscan2
- PTPRU | c.1848G>A p.Q616= | Silent (SNP) | VAF 220/483 reads (46%) | called by muse, mutect2, varscan2
- PVALEF | c.348C>T p.I116= | Silent (SNP) | VAF 217/476 reads (46%) | catalogued as rs974273981; called by muse, mutect2, varscan2
- PWWP2A | c.2061C>T p.V687= | Silent (SNP) | VAF 208/432 reads (48%) | called by muse, mutect2, varscan2
- QSOX1 | c.957C>T p.F319= | Silent (SNP) | VAF 428/753 reads (57%) | catalogued as rs1374321400; called by muse, mutect2, varscan2
- RAB32 | c.129G>A p.K43= | Silent (SNP) | VAF 241/589 reads (41%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.2397C>T p.S799= | Silent (SNP) | VAF 87/357 reads (24%) | catalogued as rs1375965153, COSV62783652; called by muse, mutect2, varscan2
- RALGPS2 | c.459C>T p.F153= | Silent (SNP) | VAF 76/307 reads (25%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.2619C>T p.L873= (on ENST00000389212; = p.L831= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 189/485 reads (39%) | catalogued as rs1324625866; called by muse, mutect2, varscan2
- RAPGEF3 | c.195G>A p.P65= (on ENST00000389212; = p.P23= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 252/556 reads (45%) | catalogued as rs769725885; called by muse, mutect2, varscan2
- RARRES2 | c.450C>T p.F150= | Silent (SNP) | VAF 188/481 reads (39%) | called by muse, mutect2, varscan2
- RASAL1 | c.2025G>A p.P675= | Silent (SNP) | VAF 285/667 reads (43%) | called by muse, mutect2, varscan2
- RCC1L | c.540C>T p.S180= | Silent (SNP) | VAF 152/357 reads (43%) | catalogued as rs782139772; called by muse, mutect2, varscan2
- RELN | c.6009T>G p.V2003= | Silent (SNP) | VAF 64/172 reads (37%) | called by muse, mutect2, varscan2
- RFX6 | c.1989G>A p.G663= | Silent (SNP) | VAF 171/483 reads (35%) | catalogued as COSV60584725; called by mutect2, varscan2
- RGSL1 | c.2991G>A p.K997= | Silent (SNP) | VAF 189/632 reads (30%) | called by muse, varscan2
- RNF186 | c.42C>T p.S14= | Silent (SNP) | VAF 210/560 reads (38%) | catalogued as rs181898691; called by muse, mutect2, varscan2
- RNFT2 | c.825C>T p.I275= | Silent (SNP) | VAF 202/491 reads (41%) | catalogued as rs768889201, COSV99985209; called by muse, varscan2
106 further variants in this file (0 protein-altering or splice-affecting, 69 silent, 37 other) are not listed here.
